Somatic mutation profile of tumor specimen TCGA-RM-A68W-01A (aliquot TCGA-RM-A68W-01A-11D-A35D-08) from TCGA case TCGA-RM-A68W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 41.8 years (15,273 days).
Specimen TCGA-RM-A68W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37c48809-46cd-4054-b9aa-849f87afb52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RM-A68W-10A (Blood Derived Normal), aliquot TCGA-RM-A68W-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8a57024-b753-4428-a35c-beaede1631bb

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGSF1 | c.3685C>T p.R1229C | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs760383828, COSV63836152, COSV99057201; called by muse, mutect2, varscan2
- SLC35B1 | c.905G>C p.G302A (on ENST00000649906; = p.G265A on NM_005827.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53601934; called by muse, mutect2, varscan2
- AMOT | c.3215G>T p.G1072V (on ENST00000371959 / NM_001113490.1; = p.G663V on NM_133265.3) | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- DDIAS | c.2650G>A p.G884S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2
- SCO2 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
